Somatic mutation profile of tumor specimen TCGA-MB-A8JK-01A (aliquot TCGA-MB-A8JK-01A-11D-A36J-09) from TCGA case TCGA-MB-A8JK, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 49.8 years (18,177 days).
Specimen TCGA-MB-A8JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c6a4f6d-194a-4ad8-a8f8-72e5575ecc42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MB-A8JK-10A (Blood Derived Normal), aliquot TCGA-MB-A8JK-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75865e14-7f1f-4def-be8c-3d63b436de11

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Frame Shift Del 4, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRA2 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57140719; called by muse, mutect2, varscan2
- C1orf52 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV99641066; called by muse, mutect2, varscan2
- CCNT2 | c.323A>G p.H108R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99751033; called by muse, mutect2, varscan2
- CTTN | c.673del p.Q225Rfs*5 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as COSV57231540; called by mutect2, pindel, varscan2
- EPHX1 | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368539734; called by muse, mutect2, varscan2
- LPXN | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as COSV101223100, COSV67717172; called by muse, mutect2, varscan2
- MYBPC2 | c.2754C>G p.N918K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV100731964; called by muse, mutect2, varscan2
- NALCN | c.2291G>A p.R764H | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.927); catalogued as rs760331955, COSV99215559; called by muse, mutect2, varscan2
- NME1-NME2 | c.551C>G p.S184C (on ENST00000555572; = p.S159C on NM_001018136.3) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100899937; called by muse, varscan2
- NRXN2 | c.5107A>G p.K1703E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV99635289; called by muse, mutect2, varscan2
- OBSCN | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV99482398; called by muse, mutect2, varscan2
- PLCB4 | c.2395A>C p.I799L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV53811309, COSV99596448; called by muse, mutect2, varscan2
- SCUBE1 | c.2899A>G p.M967V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV100683556; called by muse, mutect2, varscan2
- SEC14L5 | c.1947C>A p.Y649* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99229254; called by muse, mutect2, varscan2
- SLC6A13 | c.281A>C p.Q94P | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100570025; called by muse, mutect2
- SURF6 | c.669G>T p.R223S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV100921200; called by muse, varscan2
- TMEM132B | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100170524; called by muse, mutect2
- DBF4B | c.1623del p.G542Dfs*71 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by mutect2, pindel, varscan2
- PARGP1 | n.1923T>A | Splice Region (SNP) | VAF 91/439 reads (21%) | called by muse, mutect2, varscan2
- PRKDC | c.8590_8627del p.Q2864* | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel
- SOX4 | c.1230del p.S411Afs*44 | Frame Shift Del (DEL) | VAF 48/107 reads (45%) | called by mutect2, pindel, varscan2
- ABCB1 | c.145T>C p.L49= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99713870; called by muse, mutect2, varscan2
- CEP350 | c.768C>T p.D256= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100658336; called by muse, mutect2, varscan2
- LAMC3 | c.3823C>T p.L1275= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV62655801; called by muse, mutect2, varscan2
- SAMD9 | c.51G>A p.E17= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV101180328; called by mutect2, varscan2
